Somatic mutation profile of tumor specimen TCGA-DD-A1EC-01A (aliquot TCGA-DD-A1EC-01A-21D-A12Z-10) from TCGA case TCGA-DD-A1EC, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 20.2 years (7,363 days).
Specimen TCGA-DD-A1EC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 161a5fe7-749c-400b-8c42-50625d6f775c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-A1EC-11A (Solid Tissue Normal), aliquot TCGA-DD-A1EC-11A-11D-A12Z-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/752f9930-d7ef-4b1e-a199-36e69a8fb6cc

The open-access MAF lists 26 somatic variants for this specimen: 19 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 5, Nonsense Mutation 3, 3'UTR 1, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BIRC6 | c.5567T>C p.M1856T | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as rs953306687, COSV70203626; called by muse, mutect2
- BPTF | c.3338A>G p.D1113G | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.202); catalogued as rs1337179141, COSV58843321; called by muse, mutect2, varscan2
- BRCA2 | c.3994C>T p.H1332Y | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs863224588, COSV66449287, COSV66459140; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CADPS | c.2659G>A p.E887K | Missense Mutation (SNP) | VAF 69/268 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); catalogued as COSV51869839; called by muse, mutect2, varscan2
- FBF1 | c.1405G>C p.G469R (on ENST00000586717; = p.G483R on NM_001319193.1) | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.021); catalogued as COSV59866293; called by muse, mutect2, varscan2
- FOXK1 | c.1574T>G p.V525G | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.601); catalogued as rs761287902, COSV61067746; called by muse, mutect2, varscan2
- GPN2 | c.814G>T p.E272* | Nonsense Mutation (SNP) | VAF 14/107 reads (13%) | catalogued as COSV65129321; called by muse, mutect2, varscan2
- GPR142 | c.538G>A p.A180T | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.538); catalogued as rs1418149233, COSV59520038; called by muse, mutect2, varscan2
- IL12RB2 | c.773G>C p.R258T | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV52025704; called by muse, mutect2, varscan2
- IPO5 | c.2806G>A p.G936S | Missense Mutation (SNP) | VAF 36/170 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); catalogued as rs777731318, COSV55153400; called by muse, mutect2, varscan2
- LAMP2 | c.81T>G p.Y27* | Nonsense Mutation (SNP) | VAF 80/450 reads (18%) | catalogued as COSV99568142; called by muse, varscan2
- MCM2 | c.380G>C p.G127A | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54035962; called by muse, mutect2, varscan2
- PDE4DIP | c.6137A>G p.H2046R | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as COSV57717572; called by muse, mutect2, varscan2
- POLD1 | c.2065C>T p.R689W | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs747628342, COSV70954675; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RAPGEF2 | c.164G>C p.G55A | Missense Mutation (SNP) | VAF 46/348 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV52431857; called by muse, mutect2, varscan2
- SKAP1 | c.556C>T p.R186C | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1017266798, COSV100412433, COSV61149978; called by muse, mutect2, varscan2
- XKR7 | c.1605G>A p.W535* | Nonsense Mutation (SNP) | VAF 6/22 reads (27%) | catalogued as COSV73813355; called by muse, mutect2
- ATP13A2 | c.3461C>A p.A1154D | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.042); called by muse, mutect2
- TDRD9 | c.1908dup p.A637Cfs*12 | Frame Shift Ins (INS) | VAF 20/176 reads (11%) | called by mutect2, varscan2
- FARSB | c.297A>T p.V99= | Silent (SNP) | VAF 49/295 reads (17%) | catalogued as COSV56051612; called by muse, mutect2, varscan2
- LONRF2 | c.1830C>T p.D610= | Silent (SNP) | VAF 24/148 reads (16%) | catalogued as rs1365413576, COSV66540368, COSV66541710; called by muse, mutect2, varscan2
- SPTBN4 | c.4650C>A p.V1550= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as COSV58956048; called by muse, mutect2, varscan2
- SUPV3L1 | c.783A>G p.T261= | Silent (SNP) | VAF 49/309 reads (16%) | catalogued as COSV62845953; called by muse, mutect2, varscan2
- ZNF267 | c.378T>C p.N126= | Silent (SNP) | VAF 28/141 reads (20%) | catalogued as COSV56254967; called by muse, mutect2, varscan2
- C1orf122 | c.*31T>C | 3'UTR (SNP) | VAF 18/100 reads (18%) | catalogued as COSV100888564; called by muse, mutect2, varscan2
- RASSF5 | c.579+19322G>T | Intron (SNP) | VAF 15/106 reads (14%) | catalogued as COSV58797728; called by muse, mutect2, varscan2
